Gene-level copy-number profile of tumor specimen HTMCP-03-06-02006-01A from CGCI case HTMCP-03-06-02006, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3.
Specimen HTMCP-03-06-02006-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e9e2753f-446c-4fe4-b6a9-c06e5d89bd99.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02006-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,262 have no estimate.
https://portal.gdc.cancer.gov/files/6d6cc9b6-c7ca-4065-ba9c-8c5befe4370c

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 90; copy number 1: 64; copy number 2: 12,743; copy number 3: 6,441; copy number 4: 29,495; copy number 5: 2,441; copy number 6: 6,349; copy number 7: 48; copy number 8: 575; copy number 9: 32; copy number 10: 83.

Homozygous deletions (total copy number 0; autosomes only): 90 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:25,747,433–36,244,514, 62 genes (within-gene range 0–2) (broad region; genes not listed).
- chr4:68,509,441–68,670,652, 6 genes (within-gene range 0–2): UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr11:4,233,288–4,288,083, 4 genes: SSU72P5, SSU72P2, SSU72P6, SSU72P4.
- chr11:18,933,813–18,939,721, 2 genes: MRGPRX1, AC023078.1.
- chr13:31,739,526–32,432,954, 12 genes (within-gene range 0–2): RXFP2, FRY, EEF1DP3, AC002525.1, Metazoa_SRP, FRY-AS1, ZAR1L, BRCA2, IFIT1P1, N4BP2L1, AL137247.1, AL137247.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 115 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:126,393,032–126,564,678, 8 genes, copy number 9: CCDC37-DT, CFAP100, AC073439.1, ZXDC, UROC1, CHST13, C3orf22, RNA5SP138.
- chr3:189,631,389–189,897,276, 3 genes, copy number 9: TP63, AC078809.1, MIR944.
- chr8:123,768,439–124,372,692, 13 genes, copy number 9: FAM91A1, FER1L6, AC090753.1, FER1L6-AS1, AC100871.2, FER1L6-AS2, AC100871.1, ARF1P3, AC090921.1, RNU6-756P, AC090192.2, AC090192.1, TMEM65.
- chr8:125,430,358–125,541,373, 2 genes, copy number 10: TRIB1, AC091114.1.
- chr8:125,749,055–125,750,241, 1 gene, copy number 10: AC016074.1.
- chr8:127,578,473–127,636,867, 1 gene, copy number 10: AC104370.1.
- chr8:129,864,478–129,964,634, 5 genes, copy number 10: AC022973.2, AC022973.1, AC022973.4, AC022973.3, AC131568.1.
- chr8:131,904,093–140,458,579, 75 genes, copy number 9–10 (within-gene range 2–10) (broad region; genes not listed).
- chr8:140,094,894–140,638,283, 7 genes, copy number 9: PEG13, AC107375.1, CHRAC1, AGO2, AC067931.1, AC067931.2, ERICD.

Autosomal genes at a single copy (total copy number 1): 64. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
